Somatic mutation profile of tumor specimen TCGA-A6-2674-01A (aliquot TCGA-A6-2674-01A-02D-A270-10) from TCGA case TCGA-A6-2674, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.0 years (26,292 days).
Specimen TCGA-A6-2674-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd963c75-d94e-4278-8547-69c52b4cd1ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2674-10A (Blood Derived Normal), aliquot TCGA-A6-2674-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39aa33b0-8f02-42e3-bbea-7441701d4a09

The open-access MAF lists 123 somatic variants for this specimen: 88 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 32, Nonsense Mutation 4, Splice Region 2, Splice Site 1, Translation Start Site 1, 5'Flank 1, Intron 1, RNA 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 42/210 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PYGM | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780246932, CM092502, COSV99377718; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SIN3A | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as rs1555444885, COSV100845253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327426602, COSV51402426; called by muse, mutect2, varscan2
- ADCY2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369487048, COSV57871248; called by muse, mutect2, varscan2
- ADGRB3 | c.2968T>G p.L990V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53246784; called by muse, mutect2
- ADHFE1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs770694758, COSV52559660; called by muse, mutect2, varscan2
- ANKRD11 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs370690185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARAP1 | c.1080T>G p.F360L (on ENST00000393609 / NM_001040118.2; = p.F115L on NM_015242.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100502265; called by muse, mutect2
- ARHGAP21 | c.1998G>T p.W666C | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100256777; called by muse, mutect2
- ARHGEF3 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99576076; called by muse, mutect2, varscan2
- ARRB1 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100758210; called by muse, mutect2, varscan2
- ASB16 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs928234223, COSV99519085; called by muse, mutect2, varscan2
- BEST3 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs770709086, COSV58302523; called by muse, mutect2, varscan2
- BRWD3 | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100956506, COSV100956628; called by muse, mutect2, varscan2
- CCM2L | c.1316G>A p.R439Q (on ENST00000452892 / NM_001365692.1; = p.G418R on NM_080625.4) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs749780270, COSV52953198; called by muse, mutect2, varscan2
- CDH8 | c.905A>C p.D302A | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100184473; called by muse, mutect2
- CHD1L | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100787662; called by muse, mutect2
- CHI3L2 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100869333; called by muse, mutect2, varscan2
- CHRM2 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1470994649, COSV100282099, COSV57767109; called by muse, varscan2
- CLIP1 | c.4246C>T p.R1416C (on ENST00000620786 / NM_001247997.1; = p.R1405C on NM_002956.2) | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999756920, COSV100211294; called by muse, mutect2
- CLIP2 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554308652, COSV99791994, COSV99792486; called by muse, mutect2, varscan2
- CPNE6 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99393870; called by muse, mutect2, varscan2
- CRACD | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as COSV99950127; called by mutect2, varscan2
- CSMD3 | c.8701T>G p.C2901G (on ENST00000297405 / NM_001363185.1; = p.C2732G on NM_052900.3) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99850412; called by muse, mutect2
- CSNK2A2 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV99345519; called by muse, mutect2
- CTNS | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.415); catalogued as rs756405315, COSV99251644; called by muse, mutect2, varscan2
- CUX2 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1364584717, COSV55636062; called by muse, mutect2, varscan2
- DMP1 | c.1055G>T p.S352I | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56822469; called by muse, mutect2
- DOT1L | c.133T>G p.C45G | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101288882; called by muse, mutect2, varscan2
- DPP6 | c.1195C>G p.L399V (on ENST00000377770 / NM_001364500.2; = p.L337V on NM_001936.5) | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as COSV100128619; called by muse, varscan2
- DYNC1I1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756202767, COSV61469216; called by muse, varscan2
- FAT4 | c.10997G>T p.G3666V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100630468, COSV58713163; called by muse, mutect2
- FNBP1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.606); catalogued as rs200418146, COSV63092505; called by muse, mutect2, varscan2
- FOLH1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV57049487; called by muse, mutect2, varscan2
- GPR137B | c.969C>T p.T323= | Splice Region (SNP) | VAF 18/174 reads (10%) | catalogued as COSV100858583; called by muse, mutect2
- GTF2A1L | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100562341; called by muse, varscan2
- HBG2 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100400720; called by muse, mutect2, varscan2
- HCN1 | c.2293A>C p.N765H | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100302713; called by muse, mutect2
- HMCN1 | c.16783C>T p.R5595* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as rs1412752744, COSV54884056, COSV99633533; called by muse, mutect2, varscan2
- IFNA17 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101303486, COSV69738160; called by muse, mutect2
- KDM4D | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.139); catalogued as COSV100624387; called by muse, mutect2, varscan2
- KRT34 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as rs776876023, COSV67449815; called by muse, mutect2, varscan2
- KRTAP19-3 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.983); catalogued as COSV100477669; called by muse, mutect2
- LAMA5 | c.4718G>A p.R1573H | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs774677106, COSV53356578; called by muse, mutect2, varscan2
- LONP1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.203); catalogued as COSV100638788; called by muse, mutect2, varscan2
- MARK1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1365446821, COSV65066139; called by muse, mutect2
- MRPL20 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775815488, COSV61224529; called by muse, mutect2, varscan2
- NADSYN1 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV59815217; called by mutect2, varscan2
- NPAP1 | c.2272A>G p.T758A | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1317658999, COSV100276336; called by muse, mutect2
- OR5H6 | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.36); catalogued as COSV101051826; called by muse, mutect2, varscan2
- OR6C74 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV59607519; called by muse, mutect2, varscan2
- OR6N2 | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV100209922, COSV100210552; called by muse, mutect2
- OSBP | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99803483; called by muse, mutect2, varscan2
- OTOA | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as rs777388246, COSV53756812; called by mutect2, varscan2
- PAH | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100188493; called by muse, mutect2, varscan2
- PCDH9 | c.3469C>A p.P1157T (on ENST00000377865 / NM_203487.3; = p.P1123T on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100124187; called by muse, mutect2
- PCDHB2 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as rs782061095, COSV52029412, COSV99523661; called by muse, mutect2, varscan2
- PCSK5 | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV101377743; called by mutect2, varscan2
- PUDP | c.63T>C p.D21= | Splice Region (SNP) | VAF 10/88 reads (11%) | catalogued as COSV101128375; called by muse, mutect2
- RASGEF1B | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as COSV100021219; called by muse, mutect2
- RHOT1 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs752714402, COSV100447639; called by muse, mutect2
- RYR2 | c.10012G>T p.D3338Y | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV100773213; called by muse, mutect2, varscan2
- SOBP | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); catalogued as COSV58004112; called by muse, mutect2, varscan2
- SOX1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58378395; called by muse, mutect2, varscan2
- SPEF2 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56796378, COSV99215005; called by muse, mutect2, varscan2
- SPP2 | c.133A>T p.S45C | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV51446885; called by muse, mutect2
- SSUH2 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs116018766; called by muse, mutect2, varscan2
- SYNE1 | c.7900C>A p.Q2634K (on ENST00000367255 / NM_182961.4; = p.Q2641K on NM_033071.3) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV99582823; called by mutect2, varscan2
- SYNE3 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs769547536, COSV100516641, COSV99043712; called by muse, mutect2, varscan2
- TANC2 | c.4804G>A p.G1602R | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as COSV101267696; called by muse, mutect2
- TEP1 | c.4954C>T p.H1652Y | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99403441; called by muse, mutect2, varscan2
- TET2 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV54398346, COSV99485247; called by muse, mutect2, varscan2
- TFEB | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1311125282, COSV100026507; called by muse, mutect2, varscan2
- TGIF2LX | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52213774, COSV52213806; called by muse, mutect2
- TMEM151A | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs571174732, COSV99046246; called by muse, mutect2, varscan2
- TMEM255B | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.335); catalogued as COSV64705038; called by muse, mutect2, varscan2
- TMEM43 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.84); catalogued as rs570836197, COSV100044603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMTC3 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 39/441 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs368224038; called by muse, mutect2
- TRPC4 | c.2872G>T p.D958Y (on ENST00000379705 / NM_016179.4; = p.D963Y on NM_003306.3) | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV59022019; called by muse, mutect2
- TTLL11 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780280077, COSV58649073; called by muse, mutect2, varscan2
- TTN | c.75931G>A p.V25311I (on ENST00000591111; = p.V17887I on NM_003319.4) | Missense Mutation (SNP) | VAF 20/193 reads (10%) | PolyPhen benign (0); catalogued as rs371362606; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- USPL1 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs764273440, COSV99687640; called by muse, mutect2, varscan2
- ZNF562 | c.758T>G p.V253G (on ENST00000453372 / NM_001130032.2; = p.V181G on NM_017656.4) | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99530901; called by muse, mutect2, varscan2
- CCL3L3 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ELF3 | c.799_805+6del p.X267_splice | Splice Site (DEL) | VAF 34/178 reads (19%) | called by mutect2, varscan2
- FBXL19 | c.606del p.P205Rfs*26 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- H4-16 | c.111_115dup p.A39Vfs*30 | Frame Shift Ins (INS) | VAF 19/90 reads (21%) | called by mutect2, varscan2
- AHDC1 | c.531C>T p.I177= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV55942063; called by muse, mutect2, varscan2
- ANKRD34A | c.255C>T p.C85= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV60162203; called by muse, mutect2, varscan2
- CAD | c.3630G>A p.L1210= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV99255971; called by muse, varscan2
- CDC20 | c.1326C>T p.H442= | Silent (SNP) | VAF 18/203 reads (9%) | catalogued as COSV100196706; called by muse, mutect2
- CDH9 | c.456C>T p.I152= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV50299187, COSV50315398, COSV99161153; called by muse, mutect2
- CSMD2 | c.93C>T p.H31= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs373612518; called by muse, mutect2, varscan2
- DISP2 | c.3198G>T p.G1066= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV51118719; called by muse, mutect2
- ESPNL | c.1047G>A p.T349= | Silent (SNP) | VAF 35/305 reads (11%) | catalogued as rs371983774; called by muse, mutect2, varscan2
- FAM155A | c.153G>T p.L51= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV65590902; called by muse, mutect2, varscan2
- FLOT2 | c.975G>A p.A325= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs770754509, COSV67529287; called by muse, mutect2, varscan2
- FLT4 | c.4062C>T p.R1354= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs762533367, COSV56104340, COSV56123048, COSV99989397; called by mutect2, varscan2
- GALNT5 | c.1959C>T p.V653= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as COSV99375659; called by muse, mutect2
- GDF6 | c.1236C>T p.P412= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV54628394; called by muse, mutect2, varscan2
- GDF7 | c.1263C>T p.S421= | Silent (SNP) | VAF 56/215 reads (26%) | catalogued as rs747585645, COSV99694248; called by muse, varscan2
- GPR149 | c.93C>A p.T31= | Silent (SNP) | VAF 37/353 reads (10%) | catalogued as COSV101078271, COSV101078820; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1995G>A p.L665= | Silent (SNP) | VAF 68/346 reads (20%) | catalogued as COSV63101037; called by muse, mutect2, varscan2
- INPP4A | c.1254C>T p.I418= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as COSV99305612; called by muse, mutect2
- LSAMP | c.444C>T p.N148= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs780626885, COSV61282793; called by muse, mutect2, varscan2
- MYH7 | c.375C>G p.V125= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100806800; called by muse, mutect2, varscan2
- OR1L6 | c.144C>A p.G48= (on ENST00000373684; = p.G12= on NM_001004453.2) | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV100491021; called by muse, mutect2, varscan2
- OR2S2 | c.633G>A p.P211= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs760796586, COSV59531518; called by muse, mutect2, varscan2
- PCDHA6 | c.1671C>T p.D557= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV65341441; called by muse, mutect2, varscan2
- PCDHB3 | c.2112G>A p.S704= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV50612208, COSV50617233; called by muse, mutect2, varscan2
- PDE8B | c.333C>T p.S111= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs997861894, COSV99367756; called by muse, mutect2, varscan2
- PHF12 | c.693G>C p.L231= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV99256329; called by muse, mutect2, varscan2
- PLCL1 | c.2277G>A p.A759= | Silent (SNP) | VAF 29/199 reads (15%) | catalogued as rs1253640089, COSV70843301; called by muse, mutect2, varscan2
- PNPLA3 | c.327C>A p.L109= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV99337159, COSV99337384; called by muse, mutect2, varscan2
- PTPRS | c.2265C>T p.G755= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99512813; called by muse, mutect2, varscan2
- RPS6KL1 | c.159G>A p.A53= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs760879613, COSV100665243; called by muse, mutect2, varscan2
- TEKT3 | c.1293C>A p.I431= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100107334; called by muse, mutect2, varscan2
- TNFRSF19 | c.843C>T p.N281= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs781345372, COSV99947826; called by muse, mutect2, varscan2
- TNXB | c.9552C>T p.P3184= (on ENST00000647633; = p.P2937= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs878914056, COSV100926742; called by muse, mutect2, varscan2
- GCNT2 | c.926-35276C>T | Intron (SNP) | VAF 36/159 reads (23%) | catalogued as rs775325397, COSV53942623; called by muse, mutect2, varscan2
- HOXD4 | chr2:176150360 G>A | 5'Flank (SNP) | VAF 20/154 reads (13%) | catalogued as rs1457349764; called by muse, mutect2, varscan2
- MIR30A | n.59T>C | RNA (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
